Surgical pathology report (de-identified scan), TCGA case TCGA-78-7150, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7150-01A (Primary Tumor).

HISTORY

NSCC LLL with ? N1 metastases.

MACROSCOPIC

Four specimens received:

1: The first specimen is labelled "left lung" and consists of a left pneumonectomy specimen which measures 180 x 150 x 40 mm. Located in the apex of the left lower lobe is a large peripheral tumour measuring 70 x 65 x 45 mm. There is some puckering of the overlying pleura above the tumour but definite invasion to the pleura cannot be identified grossly. Many enlarged hilar lymph nodes and intraparenchymal lymph nodes are identified but none of these show macroscopic evidence of tumour involvement. Elsewhere the visceral pleura and parenchyma show prominent carbon pigmentation. The visceral pleura at the apex of the left upper lobe shows a cream papule. No other lesions are identified grossly. [1A, bronchial and pulmonary artery hilar resection margin; 1B-1C, bronchial lymph node; 1D, interlobar lymph node; 1E-1G, tumour with overlying pleura; 1H-1J, intraparenchymal lymph nodes from left lower lobe; 1K, intraparenchymal lymph nodes from left upper lobe; 1L, lung away from tumour in left lower lobe; 1M, lung from left upper lobe; 1N, further section of tumour and adjacent uninvolved parenchyma.]

2: The second specimen is labelled "hilar lymph node No. 1" and consists of a lymph node measuring 6 mm in diameter. [BIT, 2A.]

3: The third specimen is labelled "No. 2 hilar lymph node" and consists of two fragments of nodal tissue, the largest measuring approximately 12 mm in diameter. [Bisected, blocked with smaller fragment, 3A.]

4: The fourth specimen is labelled "lymph node No. 8" and consists of two fragments of nodal tissue, the largest measuring approximately 10 mm in diameter. The other fragment appears to contain multiple nodes on sectioning. [Each fragment bisected, BIT, 4A-4B.]

MICROSCOPY

1: Sections show a moderately to poorly differentiated adenocarcinoma which abuts but does not invade the pleura. There are extensive areas of tumour necrosis and several blood vessels within the tumour are obliterated but definite vascular invasion is not found. No lymphatic or perineural infiltration is seen. Peribronchial lymph nodes show reactive hyperplasia, anthracosis and a few small silicotic nodules but definite tumour metastases are not found. However metastatic carcinoma is present within intraparenchymal lymph nodes from the left lower lobe (1J). A single fragment sampled as a peribronchial lymph node appears to represent a fragment of the primary tumour (1D). Lung parenchyma away from the tumour shows a marked degree of peribronchial and interlobular septal anthracosis. There is also upper lobe emphysema and pleural fibrosis.

2: Sections show a small lymph node in which there is no evidence of malignancy.

3: Sections show partial replacement of the lymph node by metastatic adenocarcinoma.

4: Sections show reactive lymph nodes with anthracosis and occasional silicotic nodules. There is no evidence of metastatic carcinoma.

SUMMARY

Left pneumonectomy and lymph node sampling:

Moderately to poorly differentiated adenocarcinoma, 70 mm in diameter.

No pleural, vascular or perineural infiltration seen.

Metastases in intraparenchymal and hilar lymph nodes.

Pathological stage T2 N1.

Source: NCI Genomic Data Commons file c777a2e1-5c14-4bf2-aeda-9c39af733390 (TCGA-78-7150.99BEC792-E05E-49FD-8601-5F51E876E614.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).